Somatic mutation profile of tumor specimen TCGA-LN-A8I1-01A (aliquot TCGA-LN-A8I1-01A-11D-A36J-09) from TCGA case TCGA-LN-A8I1, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 67.2 years (24,551 days).
Specimen TCGA-LN-A8I1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a9219e1-a51e-4cab-8349-dfbf5647b437.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A8I1-10A (Blood Derived Normal), aliquot TCGA-LN-A8I1-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84e53995-6823-4733-abe5-a9f412bef695

The open-access MAF lists 94 somatic variants for this specimen: 76 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 16, In Frame Del 5, Frame Shift Ins 3, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1, 3'Flank 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.245A>C p.E82A | Missense Mutation (SNP) | VAF 97/139 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67960018, COSV67961061, COSV67962846; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 91/114 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.2542G>A p.V848I | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as rs766088822; called by muse, mutect2, varscan2
- ADCY3 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs760416852, COSV53170376; called by mutect2, varscan2
- ADNP | c.1597A>T p.M533L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs761339004; called by muse, mutect2, varscan2
- ARC | c.879G>T p.K293N | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); catalogued as COSV63078146; called by muse, mutect2, varscan2
- ARMH3 | c.1580T>C p.I527T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs759389501; called by muse, mutect2, varscan2
- CDH2 | c.1252G>T p.A418S | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52291562; called by muse, mutect2, varscan2
- CENPN | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs199499043, COSV55142100; called by muse, mutect2, varscan2
- CEP290 | c.896A>G p.D299G | Missense Mutation (SNP) | VAF 80/207 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1017259177, COSV100468689; called by muse, mutect2, varscan2
- CTTN | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 53/492 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs369658947; called by muse, mutect2, varscan2
- FNBP1 | c.871A>G p.M291V | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs764441806; called by muse, mutect2, varscan2
- FSTL5 | c.2111A>T p.H704L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV100061294; called by muse, mutect2, varscan2
- GABRA2 | c.1328G>A p.R443K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs200987678, COSV62916606; called by muse, mutect2, varscan2
- KIF26B | c.4451C>T p.P1484L | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV63640670; called by muse, mutect2, varscan2
- MAP11 | c.1058G>A p.S353N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.306); catalogued as COSV57588350; called by muse, mutect2, varscan2
- NEDD4L | c.302G>C p.R101P | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56851703; called by muse, mutect2, varscan2
- NFKBID | c.238A>G p.I80V (on ENST00000396901; = p.I232V on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs774001311; called by muse, mutect2, varscan2
- PCDHA13 | c.1510C>G p.L504V | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV56480970; called by muse, varscan2
- PLS1 | c.80A>G p.N27S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs1001398187; called by muse, mutect2, varscan2
- PNPLA8 | c.1895T>G p.L632R | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs144990439; called by muse, mutect2, varscan2
- PRKCSH | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159386031; called by muse, mutect2, varscan2
- PTPRO | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.017); catalogued as rs559417288; called by muse, mutect2, varscan2
- RASAL3 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.397); catalogued as rs1189850211; called by muse, mutect2, varscan2
- SLC35E3 | c.581T>C p.M194T | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs778747700, COSV100097963; called by muse, mutect2, varscan2
- SLC4A1 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs781454553, COSV52259363; called by muse, mutect2, varscan2
- SLC6A3 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54364087; called by muse, mutect2, varscan2
- SMOC1 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776638586, CM116129, COSV62759511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF1L | c.3731G>A p.R1244Q | Missense Mutation (SNP) | VAF 50/76 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs371427336; called by muse, mutect2, varscan2
- TNRC6A | c.4436A>G p.H1479R | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as rs755651320; called by muse, mutect2, varscan2
- TSFM | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs372337739; called by muse, mutect2, varscan2
- ATP11B | c.921G>C p.L307F | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- BRINP1 | c.1357G>T p.G453C | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP250 | c.3997G>A p.E1333K | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CERCAM | c.676dup p.A226Gfs*39 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- CLCN6 | c.1527C>T p.S509= | Splice Region (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- CNOT4 | c.1276C>G p.Q426E (on ENST00000315544 / NM_001190848.1; = p.Q423E on NM_013316.4) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPOX | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- DHX30 | c.2292_2315del p.C765_S772del (on ENST00000445061 / NM_138615.3; = p.C726_S733del on NM_014966.3) | In Frame Del (DEL) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- DSCAML1 | c.3686C>T p.A1229V (on ENST00000321322; = p.A1169V on NM_020693.4) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- GALNT15 | c.1005G>A p.W335* | Nonsense Mutation (SNP) | VAF 29/105 reads (28%) | called by muse, mutect2, varscan2
- HAUS4 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- HBP1 | c.1380T>A p.D460E | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- HBP1 | c.1382A>G p.N461S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HIF1A | c.974A>T p.Y325F | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HYDIN | c.3008A>G p.D1003G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by mutect2, varscan2
- IL15 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ING4 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- KMT2D | c.10272dup p.A3425Cfs*43 | Frame Shift Ins (INS) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- LGALS3BP | c.936_953del p.D312_S317del | In Frame Del (DEL) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- LRBA | c.3988A>G p.I1330V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAGEC1 | c.1778_1825del p.H593_P608del | In Frame Del (DEL) | VAF 54/98 reads (55%) | called by muse*, mutect2, pindel*, varscan2*
- NDUFV3 | c.299C>A p.S100Y (on ENST00000340344 / NM_001001503.2; = p.S465Y on NM_021075.4) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- NECTIN1 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 17/22 reads (77%) | called by muse, mutect2, varscan2
- OR8H2 | c.175C>G p.P59A | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- PCDHA13 | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PCDHA13 | c.1597T>G p.F533V | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.736); called by muse, varscan2
- PDGFB | c.648_656delinsGAAATT p.R217_P219delinsKF | In Frame Del (DEL) | VAF 21/59 reads (36%) | called by pindel, varscan2*
- PPM1N | c.99_119del p.A34_E40del | In Frame Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, varscan2
- PPRC1 | c.3155C>T p.P1052L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRM | c.839-1G>C p.X280_splice | Splice Site (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- RNF103 | c.1049dup p.R352Afs*13 | Frame Shift Ins (INS) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- ROS1 | c.1153A>C p.M385L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SMYD1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SOS2 | c.3293C>T p.S1098L | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- SREBF2 | c.1640_1641del p.V547Dfs*105 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | called by pindel, varscan2
- TMEM117 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- UBTF | c.1823C>A p.S608Y | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- UHRF1 | c.1858C>T p.R620* (on ENST00000612630 / NM_001290050.1; = p.R633* on NM_013282.4) | Nonsense Mutation (SNP) | VAF 29/77 reads (38%) | called by muse, mutect2, varscan2
- XPO5 | c.609G>T p.K203N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF33A | c.647A>G p.H216R (on ENST00000458705 / NM_006974.3; = p.H217R on NM_006954.2) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF382 | c.895C>G p.P299A | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF420 | c.1934G>A p.C645Y | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF569 | c.1873A>G p.I625V | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZWILCH | c.476_479del p.N159Tfs*21 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by pindel, varscan2
- ZZEF1 | c.4240G>C p.E1414Q | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ABCA1 | c.5571C>T p.A1857= | Silent (SNP) | VAF 37/45 reads (82%) | catalogued as rs371988457; called by muse, mutect2, varscan2
- ACSS3 | c.912G>A p.G304= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs1462536876, COSV54102130; called by muse, mutect2, varscan2
- BCHE | c.1674G>A p.L558= | Silent (SNP) | VAF 31/128 reads (24%) | called by muse, mutect2, varscan2
- C3orf38 | c.84C>T p.A28= | Silent (SNP) | VAF 28/39 reads (72%) | catalogued as rs757438009; called by muse, mutect2, varscan2
- CACNA1H | c.588G>A p.S196= | Silent (SNP) | VAF 82/192 reads (43%) | catalogued as rs749822770; called by muse, mutect2, varscan2
- CCDC22 | c.1722C>T p.I574= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as rs782545318; called by muse, mutect2
- CEP164 | c.1230C>A p.G410= | Silent (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- CLVS2 | c.732C>T p.I244= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV51567380, COSV99253546; called by muse, mutect2, varscan2
- CYP2W1 | c.387G>C p.T129= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV58269385; called by muse, mutect2, varscan2
- FOXK1 | c.1431G>A p.Q477= | Silent (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- KRTAP13-3 | c.258C>T p.H86= | Silent (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- MS4A6A | c.717C>T p.D239= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs760776262; called by muse, mutect2, varscan2
- MVK | c.501G>T p.P167= | Silent (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- RHOT2 | c.1659G>A p.P553= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs757394296; called by muse, mutect2, varscan2
- SPATA18 | c.906C>T p.L302= | Silent (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2, varscan2
- TGIF2LX | c.420G>A p.A140= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs371679488, COSV52213290, COSV52213984; called by muse, mutect2, varscan2
- MIR1915 | chr10:21495634 C>T | 3'Flank (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- SAR1A | c.349-1152A>G | Intron (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
